Surgical pathology report (de-identified scan), TCGA case TCGA-DA-A95Y, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Yale, specimen TCGA-DA-A95Y-06A (Metastatic).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Procedures/Addenda Attached

ICD-0-3

Melanoma NOS 8720/3

Site: Axilla lymph node 077.3

5/10/14

Specimen(s) Received:

RIGHT AXILLARY MELANOMA

FINAL DIAGNOSIS

LYMPH NODES, RIGHT AXILLA; DISSECTION:

- TEN OF TWENTY THREE LYMPH NODES POSITIVE FOR METASTATIC MELANOMA (10/23)

Pathologist:

* Report Electronically Signed Out *

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Specimen

Gross Description:

Received fresh labeled with the patient's name and "right axillary melanoma" is a 15.0 x 11.0 x 8.0 cm irregular portion of hemorrhagic, lobulated fibrofatty tissue with a minimal amount of attached skeletal muscle. Multiple lymph nodes are

[page 2 of 2]
identified, some of which are pigmented and matted, ranging from 0.3 cm to 13.0 cm in greatest dimension. A gross photograph is taken of the 2 largest positive nodes. The lymph nodes are submitted as follows: Cassettes 1-3-multiple intact nodes, cassettes 4-8-one bisected node in each, cassette 9-one trisected node, Cassettes 10-11-representative sections of 2 positive nodes in each (4 total), cassette 12-skeletal muscle.

Summary of Tissue Submitted for Microscopic Examination

Block Detail

	# Blocks	Designation	#	Description
Part 1] RIGHT AXILLARY MELANOMA	12	[Undes]	(1)	(No Description)
		MLN	(5)	Multiple LNs (each own node)
		SLN	(6)	Single Lymph Node (all 1 node)

Procedures/Addenda

TUMOR GENOTYPING

Pathologist: _____

Status: Signed Out

Findings (Results)Analysis was performed on: _____ part 1, block 11.Tumor / specimen type: Metastatic Malignant Melanoma / Lymph Nodes, Right Axilla.**None of the mutations listed below was detected in this tumor.**

In all tests in which a mutation was "not detected," only normal (wild type) sequence was identified.

Gene	Mutation: Protein	Mutation: DNA	Result
BRAF	G469A	1406G>C	not detected
	V600K	1798_1799GT>AA	not detected
	V600E	1799T>A	not detected
	V600M	1798G>A	not detected
NRAS	G12R	34G>C	not detected
	G12C	34G>T	not detected
	G12S	34G>A	not detected
	G12D	35G>A	not detected
	G12A	35G>C	not detected
	G12V	35G>T	not detected
	G13R	37G>C	not detected
	G13C	37G>T	not detected
	G13D	38G>A	not detected
	G13V	38G>T	not detected
	G13A	38G>C	not detected
	Q61K	181C>A	not detected
	Q61P	182A>C	not detected
	Q61L	182A>T	not detected
	Q61R	182A>G	not detected
	Q61H	183A>T	not detected
	Q61H	183A>C	not detected

Note: Mutations are described at the protein level using the single-letter amino acid code. X indicates the absence of an amino acid (i.e., a nonsense mutation, caused by creation of a stop codon in the DNA), and "fs" indicates a frameshift mutation. Mutations are described at the DNA level using the numbering of the reference gene's coding sequence (rather than the genomic sequence). Standard mutation nomenclature is used, according to guidelines of the Human Genome Variation Society (<http://www.hgvs.org/mutnomen/>).

Methodology

The patient sample was enriched for tumor by manual or laser-assisted dissection of formalin-fixed, paraffin-embedded (FFPE) tissue sections. DNA was extracted using a commercially available kit (_____) and quantitated on a _____ spectrophotometer. Mutation detection was performed using _____ assays run on a _____ Real-Time PCR instrument. Assay sensitivities were determined using serial dilutions (with normal DNA) of DNA from positive control samples. Whenever possible, positive controls consisted of DNA from human cell lines bearing the particular mutation being assayed. For those mutations not present in any available cell line, assay sensitivity testing was performed on positive control FFPE tumor tissues or DNA

Source: NCI Genomic Data Commons file 308d7bbd-ef93-4642-9168-86214994c1a8 (TCGA-DA-A95Y.1DD005AC-A9DF-4424-B859-1C0E238CC3CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).